Somatic mutation profile of tumor specimen MP2PRT-PAUKXK-TMP1-A (aliquot MP2PRT-PAUKXK-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUKXK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,259 days).
Specimen MP2PRT-PAUKXK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2177df49-2423-4b9e-9a51-73d16969db13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKXK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKXK-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79aa2a5c-80d9-421c-8b35-980878b6aac2

The open-access MAF lists 69 somatic variants for this specimen: 44 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 23, In Frame Del 1, Intron 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 201/445 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARNT2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 113/282 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57581968; called by muse, mutect2, varscan2
- BTBD8 | c.3719G>A p.G1240D (on ENST00000636805 / NM_001376131.1; = p.G727D on NM_015237.4) | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs1420286361; called by muse, mutect2, varscan2
- CBX2 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 299/859 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1405213397; called by muse, mutect2, varscan2
- CORO7 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 255/556 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52030406; called by muse, mutect2, varscan2
- CREBBP | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 153/365 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113088, COSV52117573; called by muse, mutect2, varscan2
- CREBBP | c.4426C>T p.P1476S | Missense Mutation (SNP) | VAF 153/366 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD084712; called by muse, mutect2, varscan2
- CYP2W1 | c.347_349del p.F116del | In Frame Del (DEL) | VAF 126/303 reads (42%) | catalogued as rs748980730; called by pindel, varscan2
- DNAH8 | c.13254G>A p.M4418I | Missense Mutation (SNP) | VAF 178/387 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs778119823, COSV59445954; called by muse, mutect2, varscan2
- EPB41L4A | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.948); catalogued as rs752147638; called by muse, mutect2, varscan2
- FAP | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 199/449 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as rs1167702696, COSV99501796; called by muse, mutect2, varscan2
- FN3KRP | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 361/618 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs202177012; called by muse, mutect2, varscan2
- L3MBTL1 | c.1486C>T p.Q496* (on ENST00000418998 / NM_001377303.1; = p.Q406* on NM_015478.7) | Nonsense Mutation (SNP) | VAF 195/389 reads (50%) | catalogued as rs777350452; called by muse, mutect2, varscan2
- MSRB3 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs370812570, COSV100377854; ClinVar: not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.4771C>T p.H1591Y | Missense Mutation (SNP) | VAF 283/931 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs1172278904, COSV99072396; called by muse, mutect2, varscan2
- PPM1G | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 230/452 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1053339381; called by muse, mutect2, varscan2
- RNF144A | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100305590; called by muse, mutect2, varscan2
- SELP | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 203/440 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV55247810, COSV99057177; called by muse, mutect2, varscan2
- SPSB4 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 250/532 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1327672735; called by muse, mutect2, varscan2
- ST8SIA3 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 164/381 reads (43%) | PolyPhen possibly damaging (0.779); catalogued as COSV60654901; called by muse, mutect2, varscan2
- TEX13A | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 262/494 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs782232598, COSV61171493; called by muse, mutect2, varscan2
- TSHZ2 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 221/508 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs781409668; called by muse, mutect2, varscan2
- XIRP2 | c.5362G>T p.D1788Y (on ENST00000628543; = p.D1963Y on NM_152381.6) | Missense Mutation (SNP) | VAF 185/403 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1452054556, COSV99740171; called by muse, mutect2, varscan2
- ABHD17C | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ACACB | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 172/390 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ACACB | c.7024G>A p.E2342K | Missense Mutation (SNP) | VAF 221/522 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG6 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- AKAP9 | c.8629T>A p.L2877I (on ENST00000359028; = p.L2853I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL12A1 | c.5270G>A p.R1757Q | Missense Mutation (SNP) | VAF 121/308 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- COL8A1 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 159/374 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA4 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 178/386 reads (46%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRK1 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GUCY1A2 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 154/341 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL40 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 296/599 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MDGA2 | c.1574G>A p.R525K (on ENST00000399232 / NM_001113498.2; = p.R227K on NM_182830.4) | Missense Mutation (SNP) | VAF 165/580 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MPND | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 198/450 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.519); called by muse, mutect2
- MYO18B | c.3298G>A p.G1100S | Missense Mutation (SNP) | VAF 186/395 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PXDNL | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 110/204 reads (54%) | SIFT tolerated (0.86); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF111 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 148/337 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SOX6 | c.2398G>A p.E800K (on ENST00000528429 / NM_001145819.2; = p.E773K on NM_017508.3) | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TRAF1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 169/554 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCCHC14 | c.241G>A p.E81K (on ENST00000268616; = p.E218K on NM_015144.3) | Missense Mutation (SNP) | VAF 147/339 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ZFP2 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 156/336 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF283 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRWD3 | c.5262G>A p.R1754= | Silent (SNP) | VAF 158/360 reads (44%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.2412G>A p.K804= (on ENST00000236925 / NM_001297707.2; = p.K793= on NM_203459.3) | Silent (SNP) | VAF 100/263 reads (38%) | called by muse, mutect2, varscan2
- CLDN4 | c.294C>T p.S98= | Silent (SNP) | VAF 277/599 reads (46%) | catalogued as rs141535832; called by muse, mutect2, varscan2
- CRISP3 | c.660A>T p.A220= (on ENST00000371159 / NM_001368123.1; = p.A202= on NM_006061.4) | Silent (SNP) | VAF 108/308 reads (35%) | called by muse, mutect2, varscan2
- ESPNL | c.1317G>A p.R439= | Silent (SNP) | VAF 452/886 reads (51%) | catalogued as rs1559268269; called by muse, mutect2, varscan2
- GLB1L2 | c.339G>A p.G113= | Silent (SNP) | VAF 163/359 reads (45%) | called by muse, mutect2, varscan2
- GOLGB1 | c.7491C>T p.L2497= | Silent (SNP) | VAF 131/313 reads (42%) | called by muse, mutect2, varscan2
- ITPKC | c.1299C>T p.F433= | Silent (SNP) | VAF 181/348 reads (52%) | called by muse, mutect2, varscan2
- KCNH8 | c.1479C>T p.F493= | Silent (SNP) | VAF 187/378 reads (49%) | called by muse, mutect2, varscan2
- MMP24 | c.1662G>A p.V554= | Silent (SNP) | VAF 159/353 reads (45%) | called by muse, mutect2, varscan2
- MYO18B | c.3297G>A p.T1099= | Silent (SNP) | VAF 186/396 reads (47%) | catalogued as rs369215277; called by muse, mutect2, varscan2
- NFIX | c.795C>T p.S265= | Silent (SNP) | VAF 135/330 reads (41%) | catalogued as COSV62175547; called by muse, mutect2, varscan2
- NOTCH1 | c.4770C>T p.F1590= | Silent (SNP) | VAF 286/933 reads (31%) | called by muse, mutect2, varscan2
- OR10K1 | c.283C>T p.L95= | Silent (SNP) | VAF 205/434 reads (47%) | catalogued as COSV56871430, COSV99193229; called by muse, mutect2, varscan2
- OR4K2 | c.51C>T p.L17= | Silent (SNP) | VAF 62/473 reads (13%) | catalogued as COSV100064807, COSV53850923; called by muse, mutect2, varscan2
- POU3F3 | c.618C>T p.L206= | Silent (SNP) | VAF 242/528 reads (46%) | called by muse, varscan2
- RBMXL2 | c.747G>A p.R249= | Silent (SNP) | VAF 262/561 reads (47%) | catalogued as COSV60980167; called by muse, mutect2, varscan2
- SLC4A4 | c.801G>A p.K267= (on ENST00000264485 / NM_001098484.3; = p.K223= on NM_003759.4) | Silent (SNP) | VAF 107/219 reads (49%) | called by muse, mutect2, varscan2
- SPSB4 | c.510C>T p.A170= | Silent (SNP) | VAF 247/526 reads (47%) | called by muse, mutect2, varscan2
- TAFA5 | c.381G>A p.K127= (on ENST00000402357 / NM_001082967.3; = p.K120= on NM_015381.7) | Silent (SNP) | VAF 144/311 reads (46%) | called by muse, mutect2, varscan2
- TMTC1 | c.1476C>T p.F492= (on ENST00000539277 / NM_001193451.2; = p.F384= on NM_175861.3) | Silent (SNP) | VAF 93/231 reads (40%) | catalogued as rs758925441; called by muse, mutect2, varscan2
- WEE1 | c.1479C>T p.T493= | Silent (SNP) | VAF 98/242 reads (40%) | called by muse, mutect2, varscan2
- ZNF200 | c.316C>T p.L106= | Silent (SNP) | VAF 144/313 reads (46%) | called by muse, mutect2, varscan2
- AL627230.3 | c.76-34G>A | Intron (SNP) | VAF 120/939 reads (13%) | called by muse, varscan2
- MUC2 | chr11:1099289 C>T | 3'Flank (SNP) | VAF 168/881 reads (19%) | catalogued as rs1361532533; called by muse, varscan2
